Surgical pathology report (de-identified scan), TCGA case TCGA-ZG-A8QY, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University Medical Center Hamburg-Eppendorf, specimen TCGA-ZG-A8QY-01A (Primary Tumor).

[page 1 of 2]
Histopathological Report

Date of cancer sample procurement:

Date of pathology report:

Patient ID:

ICD-O-3
Adenocarcinoma NOS 8140/3
Site: Prostate NOS C61.9
7/5/2014

Gross description:

1. (Prostate gland): Prostate gland: Weight: 40 g, Volume: 35 ml, Size: 3.5 x 5.5 x 4.0 cm. Adherent seminal vesicles and deferent duct: right side: 3.5 cm, left side: 4.0 cm. The surface is marked with green ink on the right side, blue ink on the left side. Apical peri-urethral a funnel shaped 0.5 x 0.4 cm measuring tissue defect marked with red ink. Total of the cross sections: 1.8 cm.
2. (Lymph nodes, right side): 5.5 x 3.0 x 1.0 cm measuring adipose tissue containing six nodes measuring up to 5.5 cm.
3. (Lymph nodes, left side): 5.0 x 2.5 x 1.0 cm measuring adipose tissue containing three nodes measuring up to 5.0 cm.

Microscopy:

1. Apex right side and left side: Right side 8 tissue blocks, left side 7 tissue blocks (total 15 tissue blocks). 3 cross sections: Right side 16 tissue blocks, left side 16 tissue blocks (total 32 tissue blocks). Basis right side and left side: Right side 9 tissue blocks, left side 14 tissue blocks (total 23 tissue blocks). Seminal vesicles right side and left side: Right side 2 tissue blocks, left side 3 tissue blocks (total 5 tissue blocks). Deferent ducts right side and left side: Right side 1 tissue block, left side 1 tissue block (total 2 tissue blocks).
2. 9 tissue blocks.
3. 6 tissue blocks.

Diagnosis:

1. (Prostate gland): Poorly differentiated prostatic adenocarcinoma, Gleason 5+4=9, (Gleason 5:55%, Gleason 4:40%, Gleason 3:5%). Tumor involves both lobes with the main focus in the prostatic basis. Maximum tumor diameter: 33 mm. No perineural invasion. Tumor infiltration into prostatic adipose tissue in 1 tissue block (invasion length: 2.1 mm, invasion depth: 1.0 mm). Tumor contact with the circumferential surgical margin in 2 tissue blocks (max. length: 2.4 mm, Gleason 4 and 5). Tumor invasion of the right seminal vesicle. Negative peri-urethral resection margin.

[page 2 of 2]
Remaining prostatic tissue with small foci prostatic intraepithelial neoplasia (high grade PIN) and signs of myoglandular hyperplasia of the prostate. Urothelium of the prostatic urethra without dysplasia. Tumor-free left seminal vesicle and deferent ducts on both sides.

2. (Lymph nodes, right side): One lymph node metastasis (5.2mm). Eight tumor-free lymph nodes (1/9).

3. (Lymph nodes, left side): Five tumor-free lymph nodes (0/5).

Tumor classification

(in consideration of immunohistochemical analyses):

pT3b, Gleason 5+4=9 (Gleason 5:55%, Gleason 4:40%, Gleason 3:5%), maximum tumor diameter: 33 mm, tumor volume approx. 7 ml (Gleason 5: 3.85 ml, Gleason 4: 2.8 ml, Gleason 3: 0.35 ml), pN1 (1/14), L1, V0, RX

Comments:

Tumor infiltration into prostatic adipose tissue in tissue block SBL3.

Tumor infiltration of the right seminal vesicle in tissue blocks SBR1, BR4A and BR2A.

Immunohistochemical analysis (D2-40, CD31) were performed on tissue blocks SBR1 and SBL1 to exclude lymphatic and venous invasion.

One macroscopic image for tumor mapping.

Source: NCI Genomic Data Commons file 7fc2617e-9821-4889-9f91-daeb70156987 (TCGA-ZG-A8QY.4A09ACD5-F433-4F49-A47A-8DC4D5807E7A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).